CCDI case PBCNFC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/4fd7cb72-a21e-474d-9873-4096eb644944

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Craniopharyngioma: ICD-O-3 morphology code: 9350/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.3 years (6,301 days).

Biospecimens (3 samples)
- Sample 0DW2VM: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DW2VQ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DW2W7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
